Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JD, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JD-01A (Primary Tumor).

[page 1 of 6]
Requesting Doctor's Information:

ICD-O-3

Tumor, adrenal cortical, oncocytic
(uncertain/unknown behavior) 8870/1

Site: Adrenal Gland, cortex C74.0

4/10 1/30/13

SPECIMEN TYPE: Adrenal Mass

CLINICAL NOTES:

L) adrenal tumour. Cancer?

MACROSCOPIC:

'Adrenal mass'. The specimen consists of an encapsulated partly lobulated tan tumour, 98 x 90 x 60mm, with an attached portion of fibro-fatty tissue, 130 x 45 x 10mm. The specimen has been incised prior to receipt. The specimen weighs 264g. The cut surface of the tumour shows it to have a homogenous tan appearance with areas cystic change (?necrosis), haemorrhage and yellow patchy areas. There appears to be a residual rim of normal adrenal gland present, 20 x 10 x 15mm. The tumour appears enclosed by the capsule.

Blocks 1-3: tumour to adjacent adrenal gland and fatty tissue

Block 4: tumour to adjacent fatty tissue

Blocks 5,6: tumour to capsule

Block 7: tumour to fatty tissue

Block 8: tumour to capsule

Blocks 9 to 13: further blocks of tumour predominantly from the centre of the specimen to sample areas of possible necrosis

MICROSCOPIC:

The 98 mm tumour is an adrenocortical oncocytic neoplasm best classified as an adrenocortical oncocytic carcinoma. The tumour is composed of oncocytic cells and much of it displays a diffuse sheet-like architecture. While some of the tumour cells are relatively small and bland, others show bizarre nuclear atypia. These bizarre cells have very large and irregular nuclei and display macronucleoli. Many show intranuclear pseudoinclusions.

The tumour appears confined to the adrenal gland. Although close to vessels and sinusoidal spaces, no unequivocal vascular space invasion is identified. Some necrotic tissue is noted very focally (block A12) but true coagulative tumour necrosis is absent. There is no significant mitotic activity (mitotic rate less than 5 per 50 hpf) however a Ki-67 stain demonstrates some proliferative activity (Ki-67 proliferative index approximately 5%). No atypical mitoses are identified.

In many areas the tumour directly underlies the capsule of the adrenal gland and this capsule with is approximately 0.2 mm in thickness is what separates the tumour from the inked surface (presumed resection margin).

The immunohistochemical profile of the tumour is typical of adrenocortical

A
T
H
O
L
O
G
Y

A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

[page 2 of 6]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal Mass

origin and is as follows:

Melan A: Positive

Calretinin: Positive

AE1/AE3 - negative.

Chromogranin - negative.

Synaptophysin - Negative.

S100 - negative.

HMB-45 - negative.

COMMENT:

Most adrenal cortical neoplasms of this size and weight are malignant. Using the Weiss scoring system I would give this a score of 3 out of 9 (with points for high nuclear grade, diffuse architecture and non-clear cell composition). This is in the malignant range and the tumour can therefore be classified as an adrenocortical carcinoma using conventional criteria.

However there is recent evidence (summarised in Ref: Bisceglia M, Ludovico O, Di Mattia A et al Adrenocortical oncocytic tumours: Report of 10 cases and review on the literature. International Journal of Surgical Pathology; July 2004; 13(3) 231-243) that adrenocortical oncocytic tumours are relatively indolent and should not be classified according to the same criteria as conventional adrenocortical tumours. Using the criteria proposed in Bisceglia et al's paper the tumour would be considered at least of "uncertain malignant potential" or "borderline" due to its large size and perhaps malignant (depending on interpretation of the area of possible necrosis in block A12). It certainly could not be considered benign and I would be reluctant to entertain a benign diagnosis given its size and bizarre cellular atypia.

Therefore, regardless of whether Weiss's original classification or Bisceglia's scheme is used, it appears best to classify the tumour as a carcinoma particularly until further is known about the natural history of adrenocortical oncocytic neoplasms. The alternative diagnosis would be a tumour of "uncertain malignant potential". I would be interested in

your opinion on this unusual case and will forward slides to him for his expert opinion.

SUMMARY:

Left adrenal tumour: Adrenocortical oncocytic carcinoma (see comment). An additional report will be issued after as reviewed the case.

[page 3 of 6]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal Mass

T-93000 M-80103

ADDITIONAL REPORT:

as follows:

COMMENT:

RESULTS - PARAFFIN IMMUNOHISTOCHEMISTRY:

AE1/AE3 - NEGATIVE
CALRETININ - POSITIVE
CHROMOGRANIN - NEGATIVE; POSITIVE INTERNAL CONTROL
HMB-45 - NEGATIVE
Ki-67 - POSITIVE (~5%)
MELAN-A - POSITIVE
SYNAPTOPHYSIN - NEGATIVE; POSITIVE INTERNAL CONTROL
S-100 - NEGATIVE; POSITIVE INTERNAL CONTROL

Interpretation: The above immunostains show that the neoplastic cells are positive for calretinin and melan-A, with negative staining for epithelial markers (AE1/AE3), and neurogenic markers (chromogranin, synaptophysin, and S-100) - consistent with an adrenal cortical primary (calretinin, 96%; melan-A, 89%). Ki-67, the proliferation index marker also shows scattered positivity at approximately 5%.

Further discussion of these findings is listed below.

NOTE: Oncocytic tumors originating from the adrenal cortex are extremely rare with just under 40 cases reported so far. So, the question of how to evaluate such tumors for risk of aggressive behavior may be somewhat problematic. For non-oncocytic adrenal neoplasms, the most widely used and reliably accepted method for such analysis is the Weiss system, as noted in your letter. In this particular system, a combination of 9 histologic features are evaluated (nuclear grade III-IV, mitotic rate >5 per 50 HPF, atypical mitosis, clear cell composition <25% of the entire tumor mass, diffuse architecture, necrosis, venous invasion, sinusoidal invasion, and capsular invasion), each with a parameter scored 0 when absent and 1 when present with a total Weiss score from 0 to 9. The presence of 2 of these criteria is considered allowable in benign

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

[page 4 of 6]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal Mass

tumors while the presence of 3 or greater criteria is indicative of malignancy. There has been some suggestion of giving some criteria more weight than others, in particular, the diagnosis of malignancy would probably be warranted by the presence of high mitotic activity, atypical mitoses, and venous invasion - even in isolation. These latter criteria would merit designation as major criteria.

Of course, as was mentioned in your letter, about a decade ago Erlandson and Reuter and Sasano et al, and others since, described small series of adrenocortical oncocytic tumor cases where the question is raised regarding this subset of adrenocortical neoplasms - specifically questioning whether the Weiss system is applicable to this particular subset. In particular, these oncocytic neoplasms start out with 3 positive criteria (composition of greater than 75% eosinophilic cells, high nuclear grade, and diffuse architecture), enough to be designated as "malignant" by the Weiss system. Yet, follow-up studies show a more benign course. Clearly then, the criteria for this particular subset needed to be re-evaluated.

We therefore have proposed the following modifications to the Weiss criteria:

1. **Major criteria:** If an oncocytic tumor exhibits a mitotic rate of more than 5 mitosis per 50 high-powered fields, any atypical mitosis, or venous invasion, it is considered malignant.
2. **Minor criteria:** If the tumor exhibits 1 of several other worrisome features (large size [$>10\text{cm}$ and/or $>200\text{gm}$], necrosis, capsular invasion, or sinusoidal invasion), the tumor is considered of uncertain malignant potential (Borderline).
3. If none of the above-listed features are present, it is reasonable to call the tumor benign.

To summarize, the presence of 1 major criterion indicates malignancy (oncocytic adrenocortical carcinoma), 1 to 4 minor criteria present indicate uncertain potential (borderline), and the absence of all major and minor criteria is indicative of benignancy (adrenocortical oncocytoma).

As far as this particular case is concerned, the H&E-sections shows an adrenal tumor largely composed of oncocytic cells forming a diffuse sheet-like architecture. Most of the tumor cells range from small and bland to medium sized cells with mild to moderate pleomorphism. The immunostains show that

[page 5 of 6]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal Mass

these neoplastic cells are positive for calretinin and melan-A, with negative staining for epithelial markers (AE1/AE3), and neurogenic markers (chromogranin, synaptophysin, and S-100) - consistent with an adrenocortical primary (calretinin, 96%; melan-A, 89% in adrenocortical tumors). Of some concern, however, there are fairly common focal areas where high concentration of very large, pleomorphic, and even bizarre tumor cells are noted. These bizarre cells have very large and irregular nuclei with prominent macronucleoli and occasional intranuclear pseudoinclusions. Rare focal areas of questionable non-coagulative necrosis are also noted (Block A-12). However no clear evidence of vascular or capsular invasion is identified and the mitotic rate is less than 5 mitosis per 50 high-powered fields (no atypical mitotic figures identified). It is noted that the Ki-67 rate of ~5%, is somewhat elevated, but we do not feel this is high enough to meet major criteria (perhaps more consistent with borderline potential). The large size of the tumor (264 grams) does meet one of the minor criteria and suggests at least borderline potential. We therefore find that the diagnosis of *oncocytic adrenocortical neoplasm of uncertain biological behaviour* is most consistent with the available data on this most unusual and interesting neoplasm.

Thank you again for sending us this most interesting case for consultation.

Reference:

Michele Bisceglia, Omella Ludovico, Antonio Di Mattia, David Ben-Dor, Judith Sandbak, Gianandrea Pasquinelli, Sean K. Lau, and Lawrence Weiss, Adrenocortical Oncocytic Tumors: Report of 10 cases and review of the literature, *International Journal of Surgical Pathology*, 12(3);231-243,2004.

DIAGNOSIS:

ADRENAL TUMOR, LEFT SIDE:

-ONCOCYTIC ADRENOCORTICAL NEOPLASM OF UNCERTAIN BIOLOGICAL BEHAVIOR (SEE COMMENT)

HISTOPATHOLOGY

ANATOMICAL PATHOLOGY

[page 6 of 6]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal Mass

REPORTING PATHOLOGIST:

(Electronic Signature)

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

Process - ship on hold.

Uncertain malignant behavior

HIVAA Discrepancy		
Care is (circle):	QUALIFIED	NOT QUALIFIED

Page 6 of 6

Where 'Collected' Indicates Rec:

No collection details given Received details entered as collection details

Source: NCI Genomic Data Commons file 318e2ebb-0138-4111-b0f8-4bab10f461fb (TCGA-OR-A5JD.AA05D1FB-38B5-4D96-B9EE-07523C95C481.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).